Somatic mutation profile of tumor specimen MP2PRT-PATBJW-TMP1-A (aliquot MP2PRT-PATBJW-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATBJW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,537 days).
Specimen MP2PRT-PATBJW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9b23ac6-036b-454a-8250-264f39fd8bff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBJW-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBJW-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef462c35-9e6e-49ce-9fcb-753bbd8116bc

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC185 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 202/495 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141894100; called by muse, mutect2, varscan2
- PLEKHD1 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 119/282 reads (42%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.984); catalogued as rs373575975; called by muse, mutect2, varscan2
- SLC25A52 | c.262C>T p.R88* (on ENST00000672005; = p.R78* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 24/550 reads (4%) | catalogued as COSV52502938; called by muse, mutect2
- SRPRA | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1345189937, COSV55007538; called by muse, mutect2
- ZC3H6 | c.2797G>T p.A933S | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as rs1301571839; called by muse, mutect2, varscan2
- CTTNBP2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FAM184A | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KLHL34 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 271/436 reads (62%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MUC17 | c.13441-1G>A p.X4481_splice | Splice Site (SNP) | VAF 114/253 reads (45%) | called by muse, mutect2, varscan2
- CHST5 | c.1119C>T p.G373= | Silent (SNP) | VAF 189/446 reads (42%) | catalogued as rs372000992; called by muse, mutect2, varscan2
- MAGI2 | c.2964C>T p.H988= | Silent (SNP) | VAF 150/324 reads (46%) | catalogued as rs553836901, COSV62643489; called by muse, mutect2, varscan2
- PCDH8 | c.1632C>A p.A544= | Silent (SNP) | VAF 32/822 reads (4%) | catalogued as rs933382244; called by muse, mutect2
- ZFYVE9 | c.3789C>T p.H1263= | Silent (SNP) | VAF 136/337 reads (40%) | called by muse, mutect2, varscan2
